CGCI case HTMCP-02-06-01164 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/17fd2902-b50d-4d6c-87aa-9b03d794ee65

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Dead; Days to death: 142 days.

Diagnoses (1)
1. Squamous cell carcinoma, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: primary; Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC clinical T: TX; AJCC clinical N: NX; AJCC clinical M: MX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 142 days.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 70; ECOG performance status: 3.
- Follow-up contact recording only the day: day 142.

Molecular and laboratory tests
- Test (IHC): Positive; Specialized molecular test: P40.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-02-06-01164-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-06-01164-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-06-01164-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Tumor status: With tumor; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Lost to follow-up: No; Tobacco smoking history indicator: 1; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Mediastinal.
- History of disease: HIV status: Negative.
- Primary pathology: Lymph nodes examined: No; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Tru-cut biopsy.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-06-01164-01A-01D-9392:
- % tumour top: 80
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-06-01164-01A-01R-9392:
- % tumour top: 80
- % tumour bottom: 70
